Gene-level copy-number profile of tumor specimen ALCH-AFEG-TTP1-A from ALCHEMIST case ALCH-AFEG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 83.6 years (30,540 days).
Specimen ALCH-AFEG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b411e36b-cac5-439d-a48a-4378c2bf3190.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AFEG-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,746 have no estimate.
https://portal.gdc.cancer.gov/files/339eb968-c7ec-4d66-968d-ef89785003fe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 3,574; copy number 2: 53,387; copy number 3: 1,883; copy number 5: 2; copy number 6: 5; copy number 13: 1; copy number 19: 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:1,267,353–1,269,267, 1 gene: AC073094.1.
- chr9:137,423,350–137,459,334, 4 genes: NOXA1, ENTPD8, NSMF, MIR7114.
- chr19:20,062,755–20,063,320, 1 gene: BNIP3P13.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:107,739,999–107,761,667, 2 genes, copy number 5: AC002467.1, CBLL1.
- chr11:1,947,278–2,001,470, 7 genes, copy number 6–19: MRPL23, MRPL23-AS1, LINC01219, H19, AC051649.3, MIR675, AC051649.2.

Autosomal genes at a single copy (total copy number 1): 774. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
